Somatic mutation profile of tumor specimen 0DIKK5 from CCDI case PBBVTK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 4.8 years (1,762 days).
Specimen 0DIKK5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 565fa5e1-c40c-4cb0-84d9-4baf3563af84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5174e5f-6441-4019-910f-b6ba8049a50c

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 4, Intron 3, Splice Site 3, 3'UTR 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 168/1294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906588, CM091418, CM091419, CM091420, COSV55118965; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL645922.1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 33/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760926358; called by muse, mutect2
- ANXA13 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 342/1732 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746759310; called by muse, mutect2, varscan2
- ERVV-2 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 85/736 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1233725958; called by muse, mutect2
- KIF2B | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 87/529 reads (16%) | catalogued as rs779266250, COSV52128868, COSV99275302; called by muse, mutect2, varscan2
- MINAR1 | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs766073576; called by muse, mutect2, varscan2
- PRR23C | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 92/811 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as rs543451209; called by muse, mutect2, varscan2
- PTGFRN | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs747362535, COSV101277381; called by mutect2, varscan2
- RARA | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54190518; called by muse, mutect2, varscan2
- SLC18A1 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 68/934 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52346967; called by muse, mutect2
- ASB15 | c.1730A>T p.E577V | Missense Mutation (SNP) | VAF 86/577 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C9orf57 | c.481T>C p.F161L (on ENST00000377024 / NM_001371610.1; = p.F139L on NM_001128618.2) | Missense Mutation (SNP) | VAF 119/357 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CCDC191 | c.2549G>A p.R850K | Missense Mutation (SNP) | VAF 177/1165 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ERBIN | c.1429-1G>A p.X477_splice | Splice Site (SNP) | VAF 145/517 reads (28%) | called by muse, mutect2, varscan2
- GALNTL5 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 74/503 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GEMIN4 | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 83/201 reads (41%) | called by muse, mutect2, varscan2
- GOLGA2 | c.2857C>T p.Q953* | Nonsense Mutation (SNP) | VAF 106/299 reads (35%) | called by muse, mutect2, varscan2
- KLRG2 | c.1006-1G>C p.X336_splice | Splice Site (SNP) | VAF 26/658 reads (4%) | called by muse, mutect2
- LPAR1 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NTSR2 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 18/598 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2
- PCDHB12 | c.1052C>A p.S351* | Nonsense Mutation (SNP) | VAF 91/1068 reads (9%) | called by muse, mutect2
- SLC17A3 | c.1084G>C p.A362P | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SPTBN5 | c.1329G>T p.K443N | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TROAP | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 103/780 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TUB | c.203+2T>G p.X68_splice | Splice Site (SNP) | VAF 22/724 reads (3%) | called by muse, mutect2
- CHADL | c.1623G>T p.L541= | Silent (SNP) | VAF 54/273 reads (20%) | called by muse, mutect2, varscan2
- CSF1R | c.2112C>T p.L704= | Silent (SNP) | VAF 90/657 reads (14%) | catalogued as rs147072380, COSV53827588; called by muse, mutect2, varscan2
- HS3ST3A1 | c.174C>G p.G58= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as rs1247278586; called by muse, mutect2
- KLHL6 | c.474G>A p.V158= | Silent (SNP) | VAF 40/1278 reads (3%) | called by muse, mutect2
- NUP155 | c.2550C>T p.A850= (on ENST00000231498 / NM_153485.3; = p.A791= on NM_004298.4) | Silent (SNP) | VAF 137/844 reads (16%) | catalogued as rs764933619; called by muse, mutect2, varscan2
- TPCN2 | c.1725G>C p.L575= | Silent (SNP) | VAF 190/476 reads (40%) | called by mutect2, varscan2
- TSPYL6 | c.258G>A p.A86= | Silent (SNP) | VAF 131/909 reads (14%) | catalogued as rs374633280; called by muse, mutect2, varscan2
- ZNF835 | c.1053G>A p.Q351= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as rs764907732; called by muse, mutect2, varscan2
- ADGRE5 | c.819+42C>A | Intron (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- IL16 | chr15:81225386 C>T | 5'Flank (SNP) | VAF 179/510 reads (35%) | called by muse, mutect2, varscan2
- MS4A14 | c.468+66G>T | Intron (SNP) | VAF 36/162 reads (22%) | catalogued as rs758334054; called by muse, mutect2, varscan2
- MUC19 | chr12:40525567 G>T | 5'Flank (SNP) | VAF 286/1168 reads (24%) | called by muse, mutect2, varscan2
- P4HA3 | c.*62G>T | 3'UTR (SNP) | VAF 73/659 reads (11%) | catalogued as rs868787236; called by muse, mutect2, varscan2
- PRELID1 | c.-56C>T | 5'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- REG1B | c.184-18C>A | Intron (SNP) | VAF 75/558 reads (13%) | called by muse, mutect2, varscan2
- SOGA1 | c.*1C>A | 3'UTR (SNP) | VAF 129/666 reads (19%) | called by muse, mutect2, varscan2
